Somatic mutation profile of tumor specimen C3L-03362-05 (aliquot CPT0284730006) from CPTAC case C3L-03362, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 41.6 years (15,189 days).
Specimen C3L-03362-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9954b926-6f8e-446a-97eb-df2fabe23920.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03362-31 (Blood Derived Normal), aliquot CPT0286840002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ddd8131d-1f00-46c4-af9c-6fc1b3917cc6

The open-access MAF lists 103 somatic variants for this specimen: 67 protein-altering or splice-affecting, 29 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 29, Intron 3, 3'UTR 2, Nonsense Mutation 2, Nonstop Mutation 1, RNA 1, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL4A5 | c.384G>A p.K128= | Splice Region (SNP) | VAF 254/269 reads (94%) | catalogued as rs1569488434, CS129382; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCG1 | c.1739C>T p.S580L | Missense Mutation (SNP) | VAF 307/581 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779638354; called by muse, mutect2, varscan2
- AGPAT2 | c.417C>G p.F139L | Missense Mutation (SNP) | VAF 16/531 reads (3%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV58248655; called by muse, mutect2
- ANK3 | c.10942G>A p.E3648K | Missense Mutation (SNP) | VAF 117/412 reads (28%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.007); catalogued as rs761370414, COSV55065631; called by muse, mutect2, varscan2
- ANK3 | c.1609C>T p.H537Y | Missense Mutation (SNP) | VAF 165/606 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55058252; called by muse, mutect2, varscan2
- ASGR2 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 127/721 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.377); catalogued as rs866477035, COSV54689893; called by muse, mutect2, varscan2
- ATG2B | c.4957C>T p.R1653C | Missense Mutation (SNP) | VAF 242/420 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as rs773625847, COSV55890358; called by muse, mutect2, varscan2
- BCO1 | c.573G>T p.K191N | Missense Mutation (SNP) | VAF 23/559 reads (4%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.91); catalogued as COSV50733134; called by muse, mutect2
- C10orf53 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 100/139 reads (72%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as rs369717123; called by muse, mutect2, varscan2
- CACNA1B | c.2020G>C p.E674Q | Missense Mutation (SNP) | VAF 205/442 reads (46%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.715); catalogued as COSV53137448; called by muse, mutect2, varscan2
- CCL8 | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 273/562 reads (49%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.458); catalogued as COSV67013971; called by muse, mutect2, varscan2
- CD163L1 | c.895G>A p.V299I | Missense Mutation (SNP) | VAF 146/758 reads (19%) | SIFT tolerated (0.73); PolyPhen benign (0.174); catalogued as rs760155715, COSV58021752; called by muse, mutect2, varscan2
- CLC | c.56C>T p.T19I | Missense Mutation (SNP) | VAF 197/478 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.04); catalogued as COSV99695564; called by muse, mutect2, varscan2
- CNGA3 | c.1496G>A p.R499Q | Missense Mutation (SNP) | VAF 147/452 reads (33%) | SIFT tolerated (0.9); PolyPhen benign (0.122); catalogued as rs374938560, COSV55624287, COSV55627390; called by muse, mutect2, varscan2
- CSF1R | c.2092G>C p.D698H | Missense Mutation (SNP) | VAF 130/396 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.928); catalogued as COSV53835440; called by muse, mutect2, varscan2
- EIF4G1 | c.1787A>G p.Y596C (on ENST00000346169 / NM_198241.3; = p.Y400C on NM_004953.5) | Missense Mutation (SNP) | VAF 106/251 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs770882414, COSV100071618; called by muse, mutect2, varscan2
- GOLGA6A | c.1927G>A p.E643K | Missense Mutation (SNP) | VAF 80/644 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1199891907; called by muse, mutect2, varscan2
- KNG1 | c.335G>A p.G112E | Missense Mutation (SNP) | VAF 115/279 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.261); catalogued as rs1312872525, COSV53981726; called by muse, mutect2, varscan2
- LCE3B | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 428/471 reads (91%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.014); catalogued as rs775955401; called by muse, mutect2, varscan2
- LTBP4 | c.727C>T p.P243S (on ENST00000308370 / NM_001042544.1; = p.P206S on NM_003573.2) | Missense Mutation (SNP) | VAF 455/978 reads (47%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs1466066852; called by muse, mutect2, varscan2
- MICALL2 | c.1451C>T p.S484F | Missense Mutation (SNP) | VAF 289/1420 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.496); catalogued as COSV52513434; called by muse, mutect2, varscan2
- MMP10 | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 250/355 reads (70%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs751532451; called by muse, varscan2
- MUC16 | c.4402G>A p.E1468K | Missense Mutation (SNP) | VAF 282/641 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); catalogued as rs267605810, COSV67493443; called by muse, mutect2, varscan2
- NBPF1 | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 109/550 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.292); catalogued as rs765066710; called by muse, mutect2, varscan2
- NCR1 | c.31G>A p.V11I | Missense Mutation (SNP) | VAF 236/1053 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as rs1569536348; called by muse, mutect2, varscan2
- NCR3LG1 | c.268C>T p.R90* | Nonsense Mutation (SNP) | VAF 142/511 reads (28%) | catalogued as rs755885523; called by muse, mutect2, varscan2
- PCDH9 | c.2035C>T p.P679S | Missense Mutation (SNP) | VAF 121/460 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.083); catalogued as COSV60529460; called by muse, mutect2, varscan2
- PDS5B | c.2123C>T p.S708L | Missense Mutation (SNP) | VAF 152/263 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV59733665; called by muse, mutect2, varscan2
- PLPP7 | c.552G>T p.M184I | Missense Mutation (SNP) | VAF 172/618 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.138); catalogued as COSV100953110; called by muse, mutect2
- SLC22A25 | c.1381C>T p.P461S | Missense Mutation (SNP) | VAF 45/218 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60600057; called by muse, mutect2, varscan2
- SLCO1B3 | c.745C>T p.P249S | Missense Mutation (SNP) | VAF 127/389 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.734); catalogued as rs904458330, COSV99682471; called by muse, mutect2, varscan2
- SLCO4C1 | c.1523C>T p.S508L | Missense Mutation (SNP) | VAF 206/378 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs529284686, COSV60520631; called by muse, mutect2, varscan2
- THEMIS | c.878G>A p.G293E | Missense Mutation (SNP) | VAF 318/364 reads (87%) | SIFT tolerated (0.11); PolyPhen benign (0.046); catalogued as rs369941356; called by muse, mutect2, varscan2
- TMC1 | c.758C>T p.S253F | Missense Mutation (SNP) | VAF 186/215 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52775683; called by muse, mutect2, varscan2
- WDFY4 | c.7087G>A p.E2363K | Missense Mutation (SNP) | VAF 131/179 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs754647092; called by muse, mutect2, varscan2
- ADAM21 | c.1012A>G p.T338A | Missense Mutation (SNP) | VAF 22/274 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.145); called by muse, mutect2
- ADGRG7 | c.943A>G p.K315E | Missense Mutation (SNP) | VAF 73/167 reads (44%) | SIFT tolerated (0.44); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ANKRD31 | c.2584G>A p.E862K | Missense Mutation (SNP) | VAF 190/310 reads (61%) | SIFT tolerated (0.21); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- APC2 | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 349/730 reads (48%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- ATP13A4 | c.533G>A p.R178K | Missense Mutation (SNP) | VAF 81/201 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CDH5 | c.2165G>A p.G722D | Missense Mutation (SNP) | VAF 219/657 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- CFLAR | c.350A>C p.K117T | Missense Mutation (SNP) | VAF 251/440 reads (57%) | SIFT tolerated (0.07); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- COL19A1 | c.1022A>C p.E341A | Missense Mutation (SNP) | VAF 68/196 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- DNAH8 | c.6659A>T p.D2220V | Missense Mutation (SNP) | VAF 380/681 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DPEP2 | c.1130G>C p.S377T | Missense Mutation (SNP) | VAF 157/551 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- GP1BA | c.422A>G p.E141G | Missense Mutation (SNP) | VAF 157/839 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- HEPHL1 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 430/619 reads (69%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- LCE3E | c.148G>A p.G50S | Missense Mutation (SNP) | VAF 625/1542 reads (41%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LMOD1 | c.1618C>T p.P540S | Missense Mutation (SNP) | VAF 425/796 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- LRP2 | c.12109A>C p.T4037P | Missense Mutation (SNP) | VAF 259/426 reads (61%) | SIFT tolerated (0.12); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- MICAL3 | c.2101C>T p.P701S | Missense Mutation (SNP) | VAF 175/207 reads (85%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- OLIG1 | c.647C>A p.P216H | Missense Mutation (SNP) | VAF 211/587 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- OTOL1 | c.559G>A p.G187R | Missense Mutation (SNP) | VAF 106/265 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- PLD2 | c.1740C>G p.Y580* | Nonsense Mutation (SNP) | VAF 133/813 reads (16%) | called by muse, mutect2
- PNMA6E | c.670G>A p.G224S | Missense Mutation (SNP) | VAF 183/257 reads (71%) | SIFT tolerated (0.37); called by muse, mutect2, varscan2
- PRRC1 | c.700A>C p.K234Q | Missense Mutation (SNP) | VAF 61/354 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PTPRD | c.4508A>G p.N1503S | Missense Mutation (SNP) | VAF 191/220 reads (87%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RP1 | c.2317C>T p.L773F | Missense Mutation (SNP) | VAF 152/170 reads (89%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- RYR2 | c.10649G>A p.R3550K | Missense Mutation (SNP) | VAF 416/779 reads (53%) | SIFT tolerated (0.19); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- SEZ6L | c.1469A>G p.K490R | Missense Mutation (SNP) | VAF 224/552 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- SLC4A10 | c.452G>A p.G151E | Missense Mutation (SNP) | VAF 239/420 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SMCO2 | c.1032A>T p.*344Yext*? | Nonstop Mutation (SNP) | VAF 177/371 reads (48%) | called by muse, mutect2, varscan2
- TAFA1 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 105/256 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRGV2 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 277/602 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- TRGV4 | c.239G>A p.G80E | Missense Mutation (SNP) | VAF 246/583 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- TXNDC11 | c.1802G>T p.C601F (on ENST00000356957 / NM_001303447.2; = p.C574F on NM_015914.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 160/567 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF776 | c.1448C>A p.S483Y | Missense Mutation (SNP) | VAF 267/717 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- ADAMTS6 | c.1266G>A p.T422= | Silent (SNP) | VAF 182/354 reads (51%) | catalogued as rs369383710; called by muse, mutect2, varscan2
- APOB | c.12921C>T p.F4307= | Silent (SNP) | VAF 60/280 reads (21%) | called by muse, mutect2, varscan2
- CD177 | c.435G>A p.G145= | Silent (SNP) | VAF 145/353 reads (41%) | called by muse, mutect2, varscan2
- CNTNAP2 | c.393G>A p.G131= | Silent (SNP) | VAF 176/369 reads (48%) | catalogued as rs768229823; called by muse, mutect2, varscan2
- CNTNAP5 | c.1938C>T p.N646= | Silent (SNP) | VAF 168/549 reads (31%) | called by muse, mutect2, varscan2
- DCDC1 | c.3984C>T p.S1328= (on ENST00000597505 / NM_001367979.1; = p.S435= on NM_020869.3) | Silent (SNP) | VAF 267/443 reads (60%) | called by muse, mutect2, varscan2
- GABRB2 | c.990C>T p.F330= | Silent (SNP) | VAF 135/450 reads (30%) | called by muse, mutect2, varscan2
- IGHE | c.411C>T p.V137= | Silent (SNP) | VAF 141/429 reads (33%) | called by muse, mutect2, varscan2
- LAMA2 | c.4767G>A p.L1589= | Silent (SNP) | VAF 272/318 reads (86%) | called by muse, mutect2
- LRCH4 | c.1299C>T p.L433= | Silent (SNP) | VAF 336/710 reads (47%) | catalogued as rs201122249; called by muse, mutect2, varscan2
- LTBP4 | c.726C>T p.G242= (on ENST00000308370 / NM_001042544.1; = p.G205= on NM_003573.2) | Silent (SNP) | VAF 407/896 reads (45%) | catalogued as COSV52583147; called by muse, varscan2
- NLRP12 | c.1074G>A p.R358= | Silent (SNP) | VAF 290/652 reads (44%) | called by muse, mutect2, varscan2
- NOMO1 | c.3300C>T p.F1100= | Silent (SNP) | VAF 294/848 reads (35%) | called by muse, mutect2, varscan2
- NPHS1 | c.783G>A p.L261= | Silent (SNP) | VAF 314/659 reads (48%) | catalogued as COSV62289741; called by muse, mutect2, varscan2
- OR8S1 | c.306C>T p.F102= | Silent (SNP) | VAF 333/380 reads (88%) | catalogued as COSV59600477; called by muse, mutect2, varscan2
- PCDHA9 | c.441G>T p.P147= | Silent (SNP) | VAF 249/538 reads (46%) | catalogued as rs575226775, COSV65333204; called by muse, mutect2, varscan2
- RBFOX1 | c.516G>A p.A172= | Silent (SNP) | VAF 252/436 reads (58%) | catalogued as rs751982525, COSV100301302; called by muse, varscan2
- RIPOR1 | c.633C>T p.L211= (on ENST00000379312 / NM_001193522.2; = p.L207= on NM_024519.4) | Silent (SNP) | VAF 166/524 reads (32%) | called by muse, mutect2, varscan2
- SCN9A | c.2751C>T p.F917= (on ENST00000303354; = p.F906= on NM_002977.3) | Silent (SNP) | VAF 146/474 reads (31%) | catalogued as COSV57621954; called by muse, mutect2, varscan2
- SCYGR5 | c.159G>T p.V53= | Silent (SNP) | VAF 141/437 reads (32%) | called by muse, mutect2, varscan2
- SEPTIN14 | c.1116A>G p.K372= | Silent (SNP) | VAF 148/346 reads (43%) | catalogued as rs1321932951; called by muse, mutect2, varscan2
- SIPA1L3 | c.4443G>A p.T1481= | Silent (SNP) | VAF 185/420 reads (44%) | catalogued as rs145924400; called by muse, mutect2, varscan2
- SLC44A5 | c.645G>A p.G215= | Silent (SNP) | VAF 56/256 reads (22%) | called by mutect2, varscan2
- SORCS3 | c.645G>A p.T215= | Silent (SNP) | VAF 118/310 reads (38%) | catalogued as rs940498244, COSV63805449; called by muse, mutect2, varscan2
- TAT | c.1248C>T p.I416= | Silent (SNP) | VAF 124/376 reads (33%) | catalogued as COSV100587727; called by muse, mutect2, varscan2
- TIMP4 | c.460C>T p.L154= | Silent (SNP) | VAF 106/260 reads (41%) | catalogued as COSV55139320; called by muse, mutect2, varscan2
- TRIM64B | c.228A>G p.L76= | Silent (SNP) | VAF 182/495 reads (37%) | called by muse, mutect2, varscan2
- ZNF212 | c.1290T>G p.G430= | Silent (SNP) | VAF 158/652 reads (24%) | called by muse, mutect2, varscan2
- ZNF74 | c.1548C>T p.I516= | Silent (SNP) | VAF 362/750 reads (48%) | catalogued as COSV62621051; called by muse, mutect2, varscan2
- FBXL7 | c.*1900T>C | 3'UTR (SNP) | VAF 143/271 reads (53%) | called by muse, mutect2, varscan2
- KIR3DX1 | n.1221C>T | RNA (SNP) | VAF 142/350 reads (41%) | called by muse, mutect2, varscan2
- MCF2L | c.170-35087G>C | Intron (SNP) | VAF 24/524 reads (5%) | called by muse, mutect2
- OSBPL9 | c.319-5377C>T | Intron (SNP) | VAF 156/276 reads (57%) | called by muse, mutect2, varscan2
- RAVER1 | c.1431+385C>T | Intron (SNP) | VAF 269/680 reads (40%) | called by muse, mutect2, varscan2
- Z99774.2 | chr22:26671291 A>T | 5'Flank (SNP) | VAF 213/492 reads (43%) | called by muse, mutect2, varscan2
- ZNF175 | c.*251C>T | 3'UTR (SNP) | VAF 191/418 reads (46%) | called by muse, mutect2, varscan2
